Somatic mutation profile of tumor specimen TCGA-DD-AADI-01A (aliquot TCGA-DD-AADI-01A-11D-A40R-10) from TCGA case TCGA-DD-AADI, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 43.6 years (15,928 days).
Specimen TCGA-DD-AADI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f53ea5a2-e67c-4cec-8192-925c2f8afebf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AADI-10A (Blood Derived Normal), aliquot TCGA-DD-AADI-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59c09d75-da01-4c86-9c2d-f0969023061f

The open-access MAF lists 124 somatic variants for this specimen: 90 protein-altering or splice-affecting, 31 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 31, Nonsense Mutation 10, Intron 3, Splice Site 3, Splice Region 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 10/128 reads (8%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- SOS1 | c.1300G>A p.G434R | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs397517148, CM070282, CM074572, COSV67677492; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACAN | c.6694A>G p.T2232A | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV100716859; called by muse, mutect2, varscan2
- ADGRB1 | c.1080G>A p.W360* | Nonsense Mutation (SNP) | VAF 5/75 reads (7%) | catalogued as COSV100029088; called by muse, mutect2
- AGAP1 | c.510G>C p.E170D | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV100363508; called by mutect2, varscan2
- ANKRD13A | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV99923802; called by muse, mutect2, varscan2
- ARHGAP9 | c.742A>T p.S248C | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV100712323; called by muse, mutect2, varscan2
- ARID2 | c.2377C>A p.Q793K | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.444); catalogued as COSV100535240, COSV57602529; called by muse, mutect2, varscan2
- BROX | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 15/344 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100572024; called by muse, mutect2
- CACNA1I | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs752533365, COSV100358990; called by muse, mutect2, varscan2
- CAPN10 | c.1336A>C p.T446P | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99549857; called by muse, mutect2
- CCDC33 | c.1204A>G p.T402A | Missense Mutation (SNP) | VAF 13/149 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.124); catalogued as rs1399893506, COSV100350383; called by muse, mutect2
- CDH1 | c.1489G>T p.E497* | Nonsense Mutation (SNP) | VAF 56/99 reads (57%) | catalogued as COSV55735504, COSV55737190, COSV55742643; called by muse, mutect2, varscan2
- CDH23 | c.7381T>C p.S2461P | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV99818475; called by muse, mutect2, varscan2
- CEP126 | c.3290T>A p.L1097* | Nonsense Mutation (SNP) | VAF 106/357 reads (30%) | catalogued as COSV99680478; called by muse, mutect2, varscan2
- COL22A1 | c.2968-1G>T p.X990_splice | Splice Site (SNP) | VAF 34/136 reads (25%) | catalogued as COSV100275825; called by muse, mutect2, varscan2
- COL23A1 | c.495+2T>C p.X165_splice | Splice Site (SNP) | VAF 19/57 reads (33%) | catalogued as rs200266099, COSV101177894; called by muse, mutect2, varscan2
- COL4A5 | c.2677+2T>C p.X893_splice | Splice Site (SNP) | VAF 21/169 reads (12%) | catalogued as COSV100086264; called by muse, mutect2, varscan2
- COLQ | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs1221084401, COSV101081948; called by muse, mutect2, varscan2
- CSMD3 | c.5821G>T p.G1941* (on ENST00000297405 / NM_001363185.1; = p.G1837* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 34/141 reads (24%) | catalogued as COSV99822258; called by muse, mutect2, varscan2
- DDX4 | c.880A>G p.N294D | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs757404630, COSV100737260; called by muse, mutect2, varscan2
- DNHD1 | c.11953A>G p.K3985E | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.092); catalogued as COSV99599311; called by muse, mutect2
- DYSF | c.4238G>A p.R1413H | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768354800, COSV50266134, COSV99243761; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EPX | c.2006T>C p.I669T | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.971); catalogued as COSV99836182; called by muse, mutect2, varscan2
- FABP7 | c.167G>A p.S56N | Missense Mutation (SNP) | VAF 84/256 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV100737867; called by muse, mutect2, varscan2
- FATE1 | c.534G>A p.W178* | Nonsense Mutation (SNP) | VAF 97/253 reads (38%) | catalogued as COSV100948087, COSV104427596; called by muse, mutect2, varscan2
- FPR2 | c.338T>C p.V113A | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1444270158, COSV60671833; called by muse, mutect2, varscan2
- FRG2B | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs756230246, COSV101423490; called by muse, mutect2, varscan2
- FRMPD1 | c.3412G>A p.G1138S | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.01); catalogued as COSV100899231; called by muse, mutect2, varscan2
- FRYL | c.8768A>T p.Q2923L | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.313); catalogued as COSV99975441; called by muse, mutect2
- GADL1 | c.1060A>T p.K354* | Nonsense Mutation (SNP) | VAF 26/80 reads (33%) | catalogued as COSV99243643, COSV99245358; called by muse, mutect2, varscan2
- GALNT12 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100899021; called by muse, mutect2, varscan2
- GALNT12 | c.937G>A p.G313R | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100899022, COSV100899212; called by muse, mutect2, varscan2
- GRXCR1 | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs772869375, COSV101295594; called by muse, mutect2, varscan2
- H3C2 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as COSV52518637, COSV52519594, COSV99451261; called by muse, mutect2, varscan2
- HACD1 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 95/295 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100778479; called by muse, mutect2, varscan2
- HCAR1 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.21); catalogued as COSV100811424; called by muse, mutect2, varscan2
- HECW2 | c.4671A>T p.E1557D | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); catalogued as COSV99645580; called by muse, mutect2, varscan2
- ICE1 | c.3658A>T p.R1220* | Nonsense Mutation (SNP) | VAF 44/144 reads (31%) | catalogued as COSV99663499; called by muse, mutect2, varscan2
- INTS6L | c.1816C>A p.Q606K | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.199); catalogued as COSV100878003; called by muse, mutect2, varscan2
- IPO7 | c.1287A>C p.K429N | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100797788, COSV63352802; called by muse, mutect2
- IRF2 | c.244A>G p.R82G | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1367364942, COSV101165754; called by muse, mutect2, varscan2
- KCNA6 | c.1213C>T p.L405F | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.035); catalogued as COSV54974675; called by muse, mutect2, varscan2
- LEMD2 | c.925A>G p.I309V | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.91); PolyPhen benign (0.005); catalogued as rs756710069, COSV99540386; called by muse, mutect2, varscan2
- MANBA | c.2015A>T p.Q672L (on ENST00000642252; = p.Q626L on NM_005908.4) | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99898210; called by muse, mutect2, varscan2
- MAP1S | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.74); catalogued as COSV100140768; called by muse, mutect2, varscan2
- MAP3K4 | c.2065G>A p.A689T | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.054); catalogued as rs764381750, COSV62335561; called by muse, mutect2, varscan2
- MARS1 | c.909G>C p.W303C | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1394419863, COSV100007027; called by muse, mutect2, varscan2
- MMP21 | c.878A>G p.H293R | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100916659; called by muse, mutect2, varscan2
- MRC2 | c.3359C>G p.A1120G | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV100315707; called by muse, mutect2
- MYO3A | c.2951G>A p.R984Q | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767330393, COSV56319068; called by muse, mutect2, varscan2
- NEDD4L | c.2064G>A p.T688= (on ENST00000400345 / NM_001144967.3; = p.T668= on NM_015277.6) | Splice Region (SNP) | VAF 10/106 reads (9%) | catalogued as rs1242344932, COSV99893146; called by muse, mutect2, varscan2
- NID2 | c.2879T>A p.I960N | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV99355823; called by muse, mutect2, varscan2
- NRCAM | c.3229G>T p.A1077S | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.045); catalogued as COSV100694122; called by muse, mutect2, varscan2
- OR10X1 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs150430213; called by muse, mutect2, varscan2
- OR14A16 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 41/380 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV100713669, COSV62927614; called by muse, mutect2, varscan2
- OR2F1 | c.467C>G p.S156C | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101231330, COSV67331559, COSV67332142; called by muse, mutect2, varscan2
- OR5H6 | c.973G>A p.V325I (on ENST00000642105; = p.V309I on NM_001005479.2) | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.024); catalogued as COSV101051738; called by muse, mutect2, varscan2
- PAPPA2 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs372509506; called by muse, mutect2, varscan2
- PCNX2 | c.819C>G p.F273L | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV50780842, COSV99265697; called by muse, mutect2, varscan2
- PFAS | c.3922G>C p.A1308P | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV100118718; called by muse, mutect2, varscan2
- PHTF2 | c.2059C>T p.L687F (on ENST00000248550 / NM_001366089.1; = p.L649F on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50338751, COSV99300925; called by muse, mutect2, varscan2
- PKLR | c.815T>C p.L272P | Missense Mutation (SNP) | VAF 72/174 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as HM080078, COSV100712765; called by muse, mutect2, varscan2
- PML | c.1334C>G p.S445* | Nonsense Mutation (SNP) | VAF 89/234 reads (38%) | catalogued as COSV99166626; called by muse, mutect2, varscan2
- PTPDC1 | c.2005G>A p.D669N (on ENST00000375360 / NM_177995.3; = p.D721N on NM_152422.4) | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.045); catalogued as COSV56624432, COSV99997283; called by muse, mutect2, varscan2
- RASAL3 | c.1870G>A p.G624S | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs1231462978, COSV99652605; called by muse, mutect2
- SCAF4 | c.1376A>G p.H459R | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.991); catalogued as COSV99740731; called by muse, mutect2, varscan2
- SEMG2 | c.1388A>T p.E463V | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.375); catalogued as COSV101033928; called by muse, mutect2
- SERPINH1 | c.922A>G p.K308E | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100824964; called by muse, mutect2
- SH3RF3 | c.716C>A p.T239K | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.02); catalogued as COSV100512223; called by muse, mutect2
- SLC16A5 | c.473T>C p.L158P | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100316923; called by muse, mutect2, varscan2
- SLC17A3 | c.1058G>C p.G353A | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.923); catalogued as COSV100399019; called by muse, mutect2, varscan2
- SLC25A23 | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99901810; called by muse, mutect2, varscan2
- SLC30A8 | c.715T>A p.Y239N | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101438180; called by muse, mutect2, varscan2
- SLIT1 | c.3968T>A p.L1323Q | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV99820441; called by muse, mutect2, varscan2
- SPAST | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 117/658 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.028); catalogued as rs944177131, COSV100188241; called by muse, mutect2, varscan2
- STK32B | c.380T>G p.I127S | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99283891; called by muse, mutect2, varscan2
- STXBP5 | c.1834G>A p.G612S | Missense Mutation (SNP) | VAF 36/460 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV99468903; called by muse, mutect2
- THOC6 | c.859G>A p.G287R | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374499488; called by muse, mutect2
- TMUB1 | c.407G>C p.R136P | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV99879492; called by muse, mutect2
- TRIM2 | c.129C>A p.C43* (on ENST00000437508; = p.C70* on NM_015271.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 59/93 reads (63%) | catalogued as COSV100107477; called by muse, mutect2, varscan2
- TTC17 | c.1109A>T p.D370V | Missense Mutation (SNP) | VAF 27/402 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99234551; called by muse, mutect2
- UGT2B10 | c.205T>A p.S69T | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as COSV99607790; called by muse, mutect2
- ZMYM2 | c.1965G>A p.W655* | Nonsense Mutation (SNP) | VAF 37/121 reads (31%) | catalogued as COSV101243456; called by muse, mutect2, varscan2
- ZNF557 | c.13G>T p.V5F | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.048); catalogued as rs377018544, COSV99422184; called by muse, mutect2, varscan2
- ZNF831 | c.3100A>T p.R1034W | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV100925730; called by muse, mutect2
- AXIN1 | c.949_979del p.S317Pfs*87 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | called by mutect2, pindel
- CD1E | c.894_904delinsTGGGT p.I299_G302delinsGC | Splice Region (DEL) | VAF 18/105 reads (17%) | called by pindel, varscan2*
- LAMB1 | c.1803del p.I601Mfs*13 | Frame Shift Del (DEL) | VAF 18/73 reads (25%) | called by mutect2, pindel, varscan2
- MRC1 | c.4112C>T p.T1371I | Missense Mutation (SNP) | VAF 159/1009 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AGBL1 | c.651C>T p.C217= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV101407780; called by muse, mutect2, varscan2
- AIPL1 | c.363C>T p.C121= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs765121760, COSV100005918; called by muse, mutect2, varscan2
- APPL1 | c.795C>T p.D265= | Silent (SNP) | VAF 31/170 reads (18%) | catalogued as COSV55701830; called by muse, mutect2, varscan2
- C1QTNF2 | c.720C>T p.Y240= (on ENST00000393975; = p.Y195= on NM_031908.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV101220797, COSV67433332; called by muse, mutect2, varscan2
- C20orf194 | c.1161T>C p.C387= | Silent (SNP) | VAF 68/374 reads (18%) | catalogued as rs915408664, COSV99330129; called by muse, mutect2, varscan2
- CACNA1G | c.2352C>T p.S784= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV100661049; called by muse, mutect2, varscan2
- CCNL1 | c.426A>G p.A142= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV99904128; called by muse, mutect2
- DNAH9 | c.10254A>T p.P3418= | Silent (SNP) | VAF 32/75 reads (43%) | catalogued as COSV99303442; called by muse, mutect2, varscan2
- FASN | c.4878C>A p.V1626= | Silent (SNP) | VAF 16/184 reads (9%) | catalogued as COSV100147209; called by muse, mutect2
- FBN2 | c.4203A>G p.G1401= | Silent (SNP) | VAF 50/173 reads (29%) | catalogued as COSV99324374; called by muse, mutect2
- FLG2 | c.1431T>C p.S477= | Silent (SNP) | VAF 9/208 reads (4%) | catalogued as COSV101165567; called by muse, mutect2
- GBA | c.477G>A p.R159= | Silent (SNP) | VAF 54/632 reads (9%) | catalogued as rs75249684, COSV100516185; called by muse, mutect2
- HERC2 | c.6912A>G p.K2304= | Silent (SNP) | VAF 48/212 reads (23%) | catalogued as rs1246114076, COSV99870342; called by muse, mutect2
- KIR3DL3 | c.1161C>T p.C387= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as rs746405337, COSV99400169; called by muse, mutect2, varscan2
- KMT2A | c.3189G>A p.V1063= | Silent (SNP) | VAF 8/152 reads (5%) | catalogued as COSV100627750; called by muse, mutect2
- LRRC66 | c.210T>C p.N70= | Silent (SNP) | VAF 56/135 reads (41%) | catalogued as COSV100602794; called by muse, mutect2, varscan2
- MUC5B | c.3183C>T p.C1061= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV101499985; called by muse, mutect2, varscan2
- NFATC2 | c.63G>A p.G21= | Silent (SNP) | VAF 108/279 reads (39%) | catalogued as COSV101043476; called by muse, mutect2, varscan2
- NRK | c.4620G>A p.K1540= | Silent (SNP) | VAF 47/291 reads (16%) | catalogued as COSV99686410; called by muse, mutect2, varscan2
- PDGFRB | c.114G>A p.P38= | Silent (SNP) | VAF 37/176 reads (21%) | catalogued as rs781077602, COSV99940049; called by muse, mutect2, varscan2
- PHKA1 | c.3180G>A p.L1060= | Silent (SNP) | VAF 69/170 reads (41%) | catalogued as COSV100262361; called by muse, mutect2, varscan2
- PSPC1 | c.433A>C p.R145= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as COSV100142111; called by muse, mutect2, varscan2
- RBBP8NL | c.636G>A p.Q212= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV99436268; called by muse, mutect2
- RYR1 | c.7575G>T p.G2525= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as COSV100614200; called by muse, mutect2, varscan2
- RYR1 | c.7701G>A p.P2567= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs1420408214, COSV100614201; called by muse, mutect2, varscan2
- SLC16A14 | c.273C>T p.G91= | Silent (SNP) | VAF 96/278 reads (35%) | catalogued as COSV99725116; called by muse, mutect2, varscan2
- SLC4A9 | c.1143G>T p.R381= (on ENST00000507527 / NM_001258428.2; = p.R357= on NM_031467.3) | Silent (SNP) | VAF 14/119 reads (12%) | catalogued as COSV99138370; called by muse, mutect2, varscan2
- ST6GAL2 | c.1038G>A p.S346= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as rs755704412, COSV62416007; called by muse, mutect2, varscan2
- TET2 | c.3234C>T p.T1078= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as rs184727510; called by muse, mutect2, varscan2
- TMUB1 | c.405C>A p.G135= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99879494; called by muse, mutect2
- ZNF548 | c.207A>T p.S69= | Silent (SNP) | VAF 7/118 reads (6%) | catalogued as COSV100277931; called by muse, mutect2
- HTR2C | c.-79-11595C>T | Intron (SNP) | VAF 20/143 reads (14%) | catalogued as COSV99347906; called by muse, mutect2, varscan2
- MAP4 | c.1999+5624del | Intron (DEL) | VAF 21/63 reads (33%) | catalogued as COSV99274549; called by mutect2, pindel, varscan2
- RASSF1 | c.369+611T>G | Intron (SNP) | VAF 18/53 reads (34%) | catalogued as COSV99204442; called by muse, mutect2, varscan2
